Gene-level copy-number profile of specimen HCM-SANG-0281-C18-85A from HCMI case HCM-SANG-0281-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-0281-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 40020055-65f9-464e-8df6-46969c8f9fad.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0281-C18-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/794f50c6-3c47-4b39-87c0-a282e5d3abfc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 799; copy number 2: 28,994; copy number 3: 23,908; copy number 4: 3,206; copy number 5: 601; copy number 6: 704; copy number 7: 162; copy number 8: 23.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,490 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,541,768–144,419,192, 34 genes, copy number 5: AC239859.1, NBPF17P, PFN1P12, RNU1-114P, RNVU1-17, RNVU1-23, RNVU1-18, AC239800.2, AC239800.1, FAM91A3P, AC239800.3, LINC02591, RNU1-143P, AC239798.1, AC239798.2, FCGR1CP, H2BP2, H3-2, AC246680.1, RPL22P5, FAM72C, SRGAP2D, IGKV1OR1-1, AC244015.1, AC244015.2, LINC02802, RNA5SP529, DRD5P2, AC245595.1, PPIAL4E, AC246785.4, RNVU1-15, AC246785.3, AC246785.2.
- chr2:242,175,181–242,175,634, 1 gene, copy number 5: RPL23AP88.
- chr8:39,451,045–39,522,852, 1 gene, copy number 7: ADAM3A.
- chr8:120,380,761–120,542,133, 2 genes, copy number 5 (within-gene range 4–5): MRPL13, MTBP.
- chr9:61,581,813–61,662,690, 4 genes, copy number 8: AL935212.3, FAM242D, Y_RNA, AL935212.1.
- chr9:61,944,232–61,945,136, 1 gene, copy number 5: CR769775.1.
- chr11:86,649–207,428, 8 genes, copy number 6 (within-gene range 4–6): OR4F2P, AC069287.1, CICP23, LINC01001, AC069287.3, RNU6-447P, BET1L, SCGB1C1.
- chr11:8,980,576–9,004,049, 1 gene, copy number 5: NRIP3.
- chr11:9,754,770–9,811,335, 2 genes, copy number 5 (within-gene range 4–5): LINC02709, SBF2-AS1.
- chr17:22,519,617–22,706,703, 14 genes, copy number 7: MTCYBP13, MTRNR2L1, AC132825.2, MTND1P15, MTND2P13, AC132825.1, NMTRS-TGA3-1, MTATP6P3, MTCO3P13, AC131055.2, AC131055.1, AC131274.3, AC131274.1, AC131274.2.
- chr20:87,250–16,053,197, 284 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr20:14,884,250–14,929,528, 1 gene, copy number 5 (within-gene range 1–5): MACROD2-AS1.
- chr20:15,552,157–64,327,972, 1,109 genes, copy number 5–8 (broad region; genes not listed).
- chr21:7,744,962–8,454,792, 26 genes, copy number 5: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1.
- chr21:44,133,610–44,210,114, 2 genes, copy number 5 (within-gene range 2–5): GATD3A, LINC01678.

Autosomal genes at a single copy (total copy number 1): 799. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
